Somatic mutation profile of tumor specimen MP2PRT-PAUKWT-TMP1-A (aliquot MP2PRT-PAUKWT-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUKWT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,548 days).
Specimen MP2PRT-PAUKWT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff651e08-96f7-4c1d-ad42-dbd3cf5cc1f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKWT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKWT-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/940f0690-7d31-48e3-9e1e-3b70227eef22

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Silent 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 188/420 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALX3 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 190/427 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as rs1159900506, COSV63929107; called by muse, mutect2, varscan2
- LGI4 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 61/625 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1342273803; called by muse, mutect2, varscan2
- MAGEB6B | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 163/184 reads (89%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.8); catalogued as rs770913834, COSV69689543; called by muse, mutect2, varscan2
- RESF1 | c.3377A>G p.Y1126C | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs774381387; called by muse, mutect2, varscan2
- TTN | c.38243C>T p.S12748F (on ENST00000591111; = p.S5324F on NM_003319.4) | Missense Mutation (SNP) | VAF 19/386 reads (5%) | PolyPhen possibly damaging (0.864); catalogued as COSV59874978; called by muse, mutect2
- DOCK2 | c.2074T>G p.F692V | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FOLR3 | c.169-1G>T p.X57_splice | Splice Site (SNP) | VAF 131/271 reads (48%) | called by muse, mutect2, varscan2
- GPR142 | c.1245C>A p.C415* | Nonsense Mutation (SNP) | VAF 184/425 reads (43%) | called by muse, mutect2, varscan2
- TEPSIN | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 266/591 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF862 | c.1761C>T p.T587= | Silent (SNP) | VAF 212/506 reads (42%) | catalogued as rs762697562, COSV56225661; called by muse, mutect2, varscan2
- RMDN2 | c.452+22110T>C | Intron (SNP) | VAF 66/267 reads (25%) | called by muse, mutect2, varscan2
